Somatic mutation profile of tumor specimen ALCH-ADAD-TTR1-A (aliquot ALCH-ADAD-TTR1-A-19-0-D-A673-36) from ALCHEMIST case ALCH-ADAD, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 58.7 years (21,447 days).
Specimen ALCH-ADAD-TTR1-A: Sample type: Slides; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3c62d455-b60c-4a2f-9eda-6c08c7049d1f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-ADAD-NB1-A (Blood Derived Normal), aliquot ALCH-ADAD-NB1-A-1-0-D-A532-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/bc51a350-56b5-4315-ab28-14639f221b4b

The open-access MAF lists 100 somatic variants for this specimen: 79 protein-altering or splice-affecting, 13 silent, 8 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 65, Silent 13, Frame Shift Del 7, Intron 4, Nonsense Mutation 4, RNA 3, Splice Region 2, 5'UTR 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 85/462 reads (18%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- AGER | c.1150G>A p.E384K | Missense Mutation (SNP) | VAF 50/273 reads (18%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.138); catalogued as rs745528625; called by muse, mutect2, varscan2
- ARFGEF2 | c.862G>T p.V288L | Missense Mutation (SNP) | VAF 84/586 reads (14%) | SIFT tolerated (0.3); PolyPhen benign (0.001); catalogued as COSV100904210; called by muse, varscan2
- ARL2 | c.199G>A p.V67M | Missense Mutation (SNP) | VAF 10/65 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs1457673148; called by muse, mutect2, varscan2
- COL4A5 | c.4819G>T p.A1607S | Missense Mutation (SNP) | VAF 107/661 reads (16%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.95); catalogued as COSV60368274; called by muse, mutect2, varscan2
- DCAF12L1 | c.189G>T p.W63C | Missense Mutation (SNP) | VAF 9/54 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0.221); catalogued as COSV64422911; called by muse, mutect2, varscan2
- DCAF4L2 | c.485C>T p.S162L | Missense Mutation (SNP) | VAF 24/266 reads (9%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.963); catalogued as rs748853957, COSV100150629, COSV60480352; called by muse, mutect2
- DST | c.10954A>G p.I3652V (on ENST00000361203 / NM_001374722.1; = p.I1240V on NM_015548.5) | Missense Mutation (SNP) | VAF 69/421 reads (16%) | SIFT tolerated (0.13); PolyPhen benign (0.237); catalogued as rs1483998442; called by muse, mutect2, varscan2
- EFR3A | c.948G>T p.Q316H | Missense Mutation (SNP) | VAF 37/558 reads (7%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.865); catalogued as rs764993491; called by muse, mutect2
- GALNT15 | c.374G>T p.R125M | Missense Mutation (SNP) | VAF 12/61 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.635); catalogued as COSV100327898; called by muse, varscan2
- GNA15 | c.505C>T p.R169C | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs199847220; called by mutect2, varscan2
- MARCHF11 | c.653G>C p.R218T | Missense Mutation (SNP) | VAF 46/261 reads (18%) | SIFT tolerated (0.08); PolyPhen benign (0.082); catalogued as COSV60133758; called by muse, mutect2, varscan2
- MAS1L | c.436C>A p.P146T | Missense Mutation (SNP) | VAF 29/188 reads (15%) | SIFT tolerated (0.1); PolyPhen benign (0.246); catalogued as COSV65808470; called by muse, mutect2, varscan2
- MYLK | c.640G>A p.G214S | Missense Mutation (SNP) | VAF 80/456 reads (18%) | SIFT tolerated (0.09); PolyPhen probably damaging (1); catalogued as rs200452099; called by muse, mutect2, varscan2
- NKX2-1 | c.825del p.A276Rfs*75 | Frame Shift Del (DEL) | VAF 4/22 reads (18%) | catalogued as rs1448653785, CD068687; called by mutect2*, pindel, varscan2*
- NPR1 | c.2011C>T p.R671C | Missense Mutation (SNP) | VAF 40/263 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs766674601, COSV64117729; called by muse, mutect2, varscan2
- NRK | c.1744C>T p.R582* | Nonsense Mutation (SNP) | VAF 36/233 reads (15%) | catalogued as rs762084637, COSV54589566, COSV54599067; called by muse, mutect2, varscan2
- NRXN1 | c.4132C>A p.P1378T | Missense Mutation (SNP) | VAF 58/369 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.007); catalogued as COSV100639851; called by muse, mutect2, varscan2
- OR6P1 | c.188T>C p.L63P | Missense Mutation (SNP) | VAF 32/340 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58108977; called by muse, mutect2
- RBFOX1 | c.80C>T p.S27L | Missense Mutation (SNP) | VAF 17/85 reads (20%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.069); catalogued as rs527782263, COSV60944925; called by muse, mutect2, varscan2
- RUVBL1 | c.602A>G p.K201R | Missense Mutation (SNP) | VAF 17/341 reads (5%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.85); catalogued as rs1168563895; called by muse, mutect2
- SDR16C5 | c.642G>T p.K214N | Missense Mutation (SNP) | VAF 43/586 reads (7%) | SIFT tolerated (0.58); PolyPhen benign (0.001); catalogued as COSV58126748, COSV58127247; called by muse, mutect2
- SLC9A6 | c.1970C>T p.P657L | Missense Mutation (SNP) | VAF 46/240 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.103); catalogued as rs782228236; called by muse, mutect2, varscan2
- SNTG1 | c.373C>A p.L125I | Missense Mutation (SNP) | VAF 42/399 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.982); catalogued as rs1380415579, COSV52437604, COSV52482654; called by muse, mutect2, varscan2
- SV2A | c.1330C>T p.R444W | Missense Mutation (SNP) | VAF 76/445 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs117711516, COSV100975285, COSV64965879; called by muse, mutect2
- ABCA6 | c.2273-4T>C | Splice Region (SNP) | VAF 42/384 reads (11%) | called by muse, mutect2, varscan2
- ABCA6 | c.2273-5C>A | Splice Region (SNP) | VAF 42/376 reads (11%) | called by muse, mutect2, varscan2
- ADGRB1 | c.637T>C p.C213R | Missense Mutation (SNP) | VAF 5/46 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- AFF2 | c.2759T>C p.L920P | Missense Mutation (SNP) | VAF 73/644 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ANKRD36 | c.701G>T p.G234V | Missense Mutation (SNP) | VAF 94/487 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.891); called by muse, mutect2, varscan2
- AP3B1 | c.2861del p.C954Lfs*47 | Frame Shift Del (DEL) | VAF 113/508 reads (22%) | called by mutect2, pindel, varscan2
- ARHGAP6 | c.433G>A p.G145R | Missense Mutation (SNP) | VAF 25/157 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.707); called by muse, mutect2, varscan2
- ATG7 | c.1982G>T p.G661V | Missense Mutation (SNP) | VAF 12/215 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); called by muse, mutect2
- ATRX | c.1775C>G p.P592R | Missense Mutation (SNP) | VAF 103/557 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- CCIN | c.408C>A p.Y136* | Nonsense Mutation (SNP) | VAF 11/354 reads (3%) | called by muse, mutect2
- CDC20 | c.206C>A p.T69N | Missense Mutation (SNP) | VAF 30/150 reads (20%) | SIFT tolerated (0.59); PolyPhen benign (0); called by muse, mutect2, varscan2
- CHD7 | c.2581G>T p.A861S | Missense Mutation (SNP) | VAF 208/533 reads (39%) | SIFT tolerated (0.71); PolyPhen benign (0.18); called by muse, mutect2, varscan2
- CNOT2 | c.1387G>T p.E463* | Nonsense Mutation (SNP) | VAF 49/394 reads (12%) | called by muse, mutect2, varscan2
- COL6A5 | c.5036A>T p.K1679M | Missense Mutation (SNP) | VAF 74/442 reads (17%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.869); called by muse, mutect2, varscan2
- COL6A6 | c.4142G>T p.R1381M | Missense Mutation (SNP) | VAF 52/375 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); called by muse, mutect2, varscan2
- DHX8 | c.1456A>G p.R486G | Missense Mutation (SNP) | VAF 27/243 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.71); called by muse, mutect2, varscan2
- DHX8 | c.1457G>T p.R486M | Missense Mutation (SNP) | VAF 26/243 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.434); called by muse, mutect2, varscan2
- DNA2 | c.1573A>G p.R525G | Missense Mutation (SNP) | VAF 44/280 reads (16%) | SIFT tolerated (0.53); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- EIF2AK4 | c.4455T>A p.H1485Q | Missense Mutation (SNP) | VAF 78/445 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.939); called by muse, mutect2, varscan2
- EVX1 | c.518G>T p.G173V | Missense Mutation (SNP) | VAF 14/139 reads (10%) | SIFT tolerated (0.07); PolyPhen benign (0.358); called by muse, mutect2, varscan2
- F5 | c.4481C>A p.S1494* | Nonsense Mutation (SNP) | VAF 146/1090 reads (13%) | called by muse, mutect2, varscan2
- GAB4 | c.365A>G p.D122G | Missense Mutation (SNP) | VAF 52/343 reads (15%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- GALK2 | c.952C>T p.P318S | Missense Mutation (SNP) | VAF 38/195 reads (19%) | SIFT tolerated (0.22); PolyPhen benign (0); called by muse, mutect2, varscan2
- GALNT15 | c.373A>G p.R125G | Missense Mutation (SNP) | VAF 12/63 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.212); called by muse, mutect2
- GAS6 | c.1463A>G p.Y488C | Missense Mutation (SNP) | VAF 15/107 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.858); called by muse, mutect2, varscan2
- GREB1L | c.3635del p.P1212Hfs*21 | Frame Shift Del (DEL) | VAF 6/56 reads (11%) | called by mutect2, pindel
- GRK7 | c.269T>A p.V90E | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.327); called by muse, mutect2, varscan2
- HMGCS2 | c.259G>T p.G87C | Missense Mutation (SNP) | VAF 11/73 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- HNRNPH2 | c.139T>A p.Y47N | Missense Mutation (SNP) | VAF 10/286 reads (3%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.819); called by muse, mutect2
- HNRNPL | c.694G>T p.V232F | Missense Mutation (SNP) | VAF 71/249 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- HRH2 | c.995C>G p.P332R | Missense Mutation (SNP) | VAF 36/190 reads (19%) | SIFT tolerated (0.55); PolyPhen benign (0); called by muse, mutect2, varscan2
- IDUA | c.755C>T p.A252V | Missense Mutation (SNP) | VAF 22/102 reads (22%) | SIFT tolerated (0.57); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- IGKV1-17 | c.53del p.P18Qfs*9 | Frame Shift Del (DEL) | VAF 54/426 reads (13%) | called by pindel, varscan2
- INTS6L | c.2540dup p.H847Qfs*7 | Frame Shift Ins (INS) | VAF 52/473 reads (11%) | called by mutect2, pindel, varscan2
- MFAP3L | c.635C>T p.T212I | Missense Mutation (SNP) | VAF 47/176 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MXRA5 | c.7435G>T p.A2479S | Missense Mutation (SNP) | VAF 51/236 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- NBEA | c.5592C>A p.N1864K | Missense Mutation (SNP) | VAF 58/476 reads (12%) | SIFT tolerated (0.84); PolyPhen benign (0.444); called by muse, mutect2, varscan2
- NKX2-1 | c.826del p.A276Rfs*75 | Frame Shift Del (DEL) | VAF 4/17 reads (24%) | called by mutect2, varscan2
- NLE1 | c.580A>T p.T194S | Missense Mutation (SNP) | VAF 24/157 reads (15%) | SIFT tolerated (0.17); PolyPhen benign (0.089); called by muse, mutect2, varscan2
- OR10A3 | c.224C>G p.A75G | Missense Mutation (SNP) | VAF 39/200 reads (20%) | SIFT tolerated (0.06); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- PCDHA7 | c.1711G>C p.G571R | Missense Mutation (SNP) | VAF 36/221 reads (16%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- PDE12 | c.860A>G p.K287R | Missense Mutation (SNP) | VAF 51/298 reads (17%) | SIFT tolerated (0.32); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- PTCD3 | c.894T>G p.I298M | Missense Mutation (SNP) | VAF 22/167 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- ROBO2 | c.3534T>A p.F1178L | Missense Mutation (SNP) | VAF 65/407 reads (16%) | SIFT tolerated (0.53); PolyPhen benign (0); called by muse, mutect2, varscan2
- RUVBL1 | c.603G>T p.K201N | Missense Mutation (SNP) | VAF 16/332 reads (5%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.992); called by muse, mutect2
- SIGLEC7 | c.758C>A p.T253K | Missense Mutation (SNP) | VAF 17/141 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.838); called by muse, mutect2, varscan2
- SRCIN1 | c.3289G>A p.A1097T (on ENST00000621492; = p.A1063T on NM_025248.3) | Missense Mutation (SNP) | VAF 20/76 reads (26%) | SIFT tolerated (0.07); PolyPhen benign (0.049); called by muse, mutect2, varscan2
- STAT2 | c.905C>T p.A302V | Missense Mutation (SNP) | VAF 21/113 reads (19%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.949); called by muse, mutect2, varscan2
- TMEM132C | c.2914del p.V972Cfs*27 | Frame Shift Del (DEL) | VAF 11/78 reads (14%) | called by mutect2, pindel, varscan2
- TRPM5 | c.2863G>T p.V955F | Missense Mutation (SNP) | VAF 33/229 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- XYLT1 | c.554del p.P185Hfs*9 | Frame Shift Del (DEL) | VAF 77/401 reads (19%) | called by mutect2, pindel, varscan2
- ZFP91 | c.1097A>G p.H366R | Missense Mutation (SNP) | VAF 25/149 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.666); called by muse, mutect2, varscan2
- ZNF236 | c.1049G>T p.S350I | Missense Mutation (SNP) | VAF 37/196 reads (19%) | SIFT tolerated (0.07); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- ZNF423 | c.3029A>T p.E1010V (on ENST00000563137 / NM_001379286.1; = p.E1002V on NM_015069.4) | Missense Mutation (SNP) | VAF 9/172 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.492); called by muse, mutect2
- ABCC1 | c.432A>T p.V144= | Silent (SNP) | VAF 53/259 reads (20%) | called by muse, mutect2, varscan2
- CNOT2 | c.1386G>T p.V462= | Silent (SNP) | VAF 50/397 reads (13%) | called by muse, mutect2, varscan2
- DCAF12L2 | c.984C>T p.H328= | Silent (SNP) | VAF 50/197 reads (25%) | catalogued as rs763667428; called by muse, mutect2, varscan2
- KNDC1 | c.2793T>C p.F931= | Silent (SNP) | VAF 40/196 reads (20%) | called by muse, mutect2, varscan2
- KRT24 | c.399G>T p.G133= | Silent (SNP) | VAF 34/352 reads (10%) | called by muse, mutect2
- MEIOC | c.2064T>C p.F688= | Silent (SNP) | VAF 26/224 reads (12%) | called by muse, mutect2, varscan2
- OR4E2 | c.420C>A p.V140= | Silent (SNP) | VAF 29/198 reads (15%) | catalogued as rs1427700942, COSV100330123; called by muse, mutect2, varscan2
- PLPPR5 | c.309T>A p.T103= | Silent (SNP) | VAF 54/399 reads (14%) | called by muse, mutect2, varscan2
- ROBO1 | c.4080G>A p.G1360= | Silent (SNP) | VAF 26/157 reads (17%) | called by muse, mutect2, varscan2
- SAMD9L | c.3162G>T p.L1054= | Silent (SNP) | VAF 52/313 reads (17%) | called by muse, mutect2, varscan2
- SLITRK5 | c.1824G>T p.S608= | Silent (SNP) | VAF 69/294 reads (23%) | catalogued as rs768554234, COSV100280419, COSV61527230; called by muse, mutect2, varscan2
- SMC1B | c.2832G>A p.S944= | Silent (SNP) | VAF 38/184 reads (21%) | catalogued as rs546593612; called by muse, mutect2, varscan2
- VPS13C | c.3762G>A p.Q1254= (on ENST00000644861 / NM_020821.3; = p.Q1211= on NM_017684.5) | Silent (SNP) | VAF 91/537 reads (17%) | called by muse, mutect2, varscan2
- AC004801.4 | n.2550G>A | RNA (SNP) | VAF 31/222 reads (14%) | called by muse, mutect2, varscan2
- AC092471.1 | n.817G>T | RNA (SNP) | VAF 16/158 reads (10%) | called by muse, varscan2
- ANKS1B | c.3067-6785T>A | Intron (SNP) | VAF 82/292 reads (28%) | called by muse, mutect2, varscan2
- COL24A1 | c.4782+844C>T | Intron (SNP) | VAF 10/60 reads (17%) | catalogued as rs1156778273; called by muse, varscan2
- HES2 | c.-6C>A | 5'UTR (SNP) | VAF 8/37 reads (22%) | called by muse, mutect2, varscan2
- MAP2K1 | c.1022+45T>A | Intron (SNP) | VAF 54/343 reads (16%) | called by muse, mutect2, varscan2
- MSL3P1 | n.601C>T | RNA (SNP) | VAF 87/510 reads (17%) | catalogued as rs940195273; called by muse, mutect2, varscan2
- NEURL4 | c.1631+14G>T | Intron (SNP) | VAF 6/29 reads (21%) | called by muse, mutect2, varscan2
